Gene-level copy-number profile of tumor specimen HCM-CSHL-0085-C24-01A from HCMI case HCM-CSHL-0085-C24, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Ampulla of Vater; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 56.0 years (20,466 days).
Specimen HCM-CSHL-0085-C24-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f66f7245-ac63-4a43-9bf7-f7e34a897491.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0085-C24-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,715 have no estimate.
https://portal.gdc.cancer.gov/files/8f13c4ab-8106-448f-8bbe-0b2ac01b7b12

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 2,006; copy number 2: 43,903; copy number 3: 12,695; copy number 4: 291; copy number 5: 3; copy number 6: 3; copy number 9: 2.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:196,774,813–196,795,407, 1 gene: CFHR3.
- chr2:242,025,183–242,026,176, 1 gene (within-gene range 0–2): AC093642.1.
- chr2:242,047,695–242,084,233, 1 gene (within-gene range 0–2): LINC01880.
- chr2:242,175,181–242,175,634, 1 gene: RPL23AP88.
- chr5:121,040,090–121,044,032, 1 gene: AC008565.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,784,376–143,797,108, 3 genes, copy number 5: AC239800.3, LINC02591, RNU1-143P.
- chr1:143,874,793–143,883,575, 1 gene, copy number 6 (within-gene range 2–6): FCGR1CP.
- chr6:170,615,515–170,738,536, 1 gene, copy number 9 (within-gene range 2–9): AL672310.1.
- chr6:170,736,173–170,737,777, 1 gene, copy number 9: AL731684.1.
- chr21:9,068,361–9,129,752, 1 gene, copy number 6 (within-gene range 2–6): TEKT4P2.
- chr21:9,088,188–9,088,391, 1 gene, copy number 6: CR392039.2.

Autosomal genes at a single copy (total copy number 1): 619. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
